Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8191, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8191-01A (Primary Tumor).

[page 1 of 8]
Surgical Pathology Report

--- Clinical History ---

Malignant neoplasm of frontal lobe of brain ICD-9 Code: 191.1. Medical history: Migraines, brain mass, bicuspid aortic valve, kidney stone, depression.

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

- A. Right insular tumor, biopsy:
- Anaplastic oligodendroglioma, (WHO grade III). See comment.
- B. Right insular tumor, biopsy:
- Anaplastic oligodendroglioma, WHO grade III, see comment.
- C. Right insular tumor, excision:
- Anaplastic oligodendroglioma, WHO grade III, see comment.

---Comment---

Comment: Assays for 1p and 19q deletions are pending.

[page 2 of 8]
Addendum

Pathology Core Facility, Molecular Diagnostic Laboratory
Department of Pathology and Laboratory Medicine

RESULTS

total number of LSI 19q13 signals by the total number of LSI 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping

[page 3 of 8]
nuclei in the neoplastic glial cells at

two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. References ranges for our laboratory for allelic loss versus no

allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken

from at least 2 sets of 20 interphase nuclei at 2 different areas with nonoverlapping nuclei is consistent with allelic loss. FISH and H&E stained slides have been reviewed by the interpreting pathologist.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and

their performance characteristics determined by the Pathology Core Facility of They have not been
cleared by the US Food and

Drug Administration. The FDA has determined that such clearance or approval is not necessary.

---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Right insular tumor: (FROZEN SECTION PERFORMED)
- Consistent with low grade glioma.

Note: Report given to

Examining pathologist:

---MICROSCOPIC:---

The specimen consists of hypercellular neural parenchyma with areas containing oligodendrocytes with round nuclei and perinuclear cytoplasmic clearing and background thin, delicate vasculature. Focal areas with increased cellularity with elongated and pleomorphic cells are present. There are also increased mitotic figures in these specific areas; however, there is no evidence of necrosis or microvascular proliferation. Immunohistochemical stains were performed on block C. The tumor cells are positive for GFAP, and Ki-67 shows a manual proliferation index of approximately 5-6%. In situ hybridization for deletion 1p/19q is pending, and the results will be issued in an addendum report. The histologic and immunohistochemical features are consistent with the WHO classification of anaplastic oligodendroglioma, grade III. Clinical correlation is recommended.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the

[page 4 of 8]
Immunohistochemistry and Histology Core Facility laboratories in the
Department of Pathology at and are not required to
have nor do they have FDA approval.

---SPECIMEN(S) RECEIVED:---

NBX

A: Neuropathy, BX

B: Neuropathy, BX

C: Neuropathy, BX

---GROSS DESCRIPTION:---

The specimens are received in three properly labeled containers with the patient's name and accession number, one of which was submitted for frozen section.

A. The specimen is designated "right insular tumor" and consists of a 0.4 x 0.2 x 0.1 cm aggregate of soft tissue fragments. The specimen was submitted entirely for frozen section and is resubmitted as received in cassette AF1. TE 1

B. The specimen is designated "right insular tumor" and consists of a 2.3 x 1.1 x 0.3 cm aggregate of gray-tan soft tissue fragments. TE 1

C. The specimen is designated "right insular tumor" and consists of a 3.7 x 3.4 x 0.8 cm aggregate of gray-white, gelatinous soft tissue fragments. TE 4

Lab Use Only:

Gross description by:

[page 5 of 8]
Surgical Pathology Report

--- Clinical History ---

Malignant neoplasm of frontal lobe of brain ICD-9 Code: 191.1. Medical history: Migraines, brain mass, bicuspid aortic valve, kidney stone, depression.

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

- A. Right insular tumor, biopsy:
- Anaplastic oligodendroglioma, (WHO grade III). See comment.
- B. Right insular tumor, biopsy:
- Anaplastic oligodendroglioma, WHO grade III, see comment.
- C. Right insular tumor, excision:
- Anaplastic oligodendroglioma, WHO grade III, see comment.

---Comment---

Comment: Assays for 1p and 19q deletions are pending.

[page 6 of 8]
---Addendum Report---

Addendum

Status: Signed Out

Detection of 1p36 and 19q by LSIe 1p36/LSI 1q25 and LSI 19q13/19p13
Dual-Color Probe Sets

Pathology Core Facility, Molecular Diagnostic Laboratory
Department of Pathology and Laboratory Medicine

Case No Outside Case#:
Pathologist Patient Name:
Source of case Patient MRN:

Block used

Tissue fixation formalin-fixed tissue

Tissue source Brain

RESULTS

Ratio of 0.87 Cell count of 1p/1q: 107

Ratio of 0.84 Cell count of 19q/19p: 108

Interpretation of Results: A) No loss of 1p & B) Loss of 19q

Interpretation of findings:

A) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 1q25 signals and 2 to 3 chromosome 1p36 signals (locus of interest), and the ratio of 1p36/1q25 Ratio was >0.8 . The results are consistent with no loss of the 1p36 locus of interest.

B) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 19p13 signals and 2 to 3 chromosome 19q13 signals (locus of interest), and the ratio of 19q13/19p13 Ratio was >0.8 . The results are consistent with no loss of the 19q13 locus of interest.

Number of Observers: 2

Test Interpreted By:

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning imaging

workstation (Duet) and accompanying imaging analysis software (BioView). The resultant FISH section/slide is then presented to the interpreting Pathologist, who will

reviews the FISH results from BioView and compares them to the results manually observed under an Olympus Fluorescence Microscope. Therefore the ratio is enumerated

by computer-aided counting(BioView) as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of LSI 1p36 signals by the total number of LSI 1q25 signals in at least 20 interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by dividing the

total number of LSI 19q13 signals by the total number of LSI 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping

[page 7 of 8]
nuclei in the neoplastic glial cells at

two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. References ranges for our laboratory for allelic loss versus no

allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken

from at least 2 sets of 20 interphase nuclei at 2 different areas with nonoverlapping nuclei is consistent with allelic loss. FISH and H&E stained slides have been reviewed

by the interpreting pathologist.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and

their performance characteristics determined by the Pathology Core Facility of They have not been
cleared by the US Food and

Drug Administration. The FDA has determined that such clearance or approval is not necessary.

---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Right insular tumor: (FROZEN SECTION PERFORMED)
- Consistent with low grade glioma.

Note: Report given to

Examining pathologist:

---MICROSCOPIC:---

The specimen consists of hypercellular neural parenchyma with areas containing oligodendrocytes with round nuclei and perinuclear cytoplasmic clearing and background thin, delicate vasculature. Focal areas with increased cellularity with elongated and pleomorphic cells are present. There are also increased mitotic figures in these specific areas; however, there is no evidence of necrosis or microvascular proliferation. Immunohistochemical stains were performed on block C. The tumor cells are positive for GFAP, and Ki-67 shows a manual proliferation index of approximately 5-6%. In situ hybridization for deletion 1p/19q is pending, and the results will be issued in an addendum report. The histologic and immunohistochemical features are consistent with the WHO classification of anaplastic oligodendroglioma, grade III. Clinical correlation is recommended.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the

[page 8 of 8]
Immunohistochemistry and Histology Core Facility laboratories in the
Department of Pathology at and are not required to
have nor do they have FDA approval.

---SPECIMEN(S) RECEIVED:---

NBX

A: Neuropathy, BX

B: Neuropathy, BX

C: Neuropathy, BX

---GROSS DESCRIPTION:---

The specimens are received in three properly labeled containers with the patient's name and accession number, one of which was submitted for frozen section.

A. The specimen is designated "right insular tumor" and consists of a 0.4 x 0.2 x 0.1 cm aggregate of soft tissue fragments. The specimen was submitted entirely for frozen section and is resubmitted as received in cassette AF1. [REDACTED]

B. The specimen is designated "right insular tumor" and consists of a 2.3 x 1.1 x 0.3 cm aggregate of gray-tan soft tissue fragments. [REDACTED]

C. The specimen is designated "right insular tumor" and consists of a 3.7 x 3.4 x 0.8 cm aggregate of gray-white, gelatinous soft tissue fragments. [REDACTED]

Lab Use Only:

Gross description by:

Source: NCI Genomic Data Commons file 33b74a6a-ef3d-4de8-8691-5dbaa51cfbf6 (TCGA-FG-8191.33D30363-B7FB-479F-A985-A9F3C468AB95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).